CCDI case PBBKKT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b8f32a8f-6bc3-47b0-aaed-5cfd7733fb43

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.0 years (4,750 days).

Biospecimens (3 samples)
- Sample 0DB97O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DB97U: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DB981: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
